Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3X, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3X-01A (Primary Tumor).

Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

DIAGNOSIS

(A) RIGHT LUNG, BIOPSY:

CONSISTENT WITH EPITHELIOID MALIGNANT MESOTHELIOMA (SEE COMMENT)

ICD-03
Mesothelioma, epithelioid, malignant
Site: Right Lung NOS
905213
C34.9
W 6/13/14

COMMENT

Immunohistochemical studies show the tumor is positive for calretinin, WT-1 and D2-40; negative for CEA, CD15, MOC31, CK5/6 and mesothelin. The morphologic features together with immunoprofile are consistent with epithelioid malignant mesothelioma.

GROSS DESCRIPTION

(A) RIGHT LUNG BIOPSY – Multiple pink-red core biopsy fragments ranging from 0.1 x 0.1 cm to 0.4 x 0.1 cm. Entirely submitted in A.

CLINICAL HISTORY

Pleural based mass

SNOMED CODES

T-28000, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file a1ebd3d3-cc3c-4ff4-8959-f5175b8d3fac (TCGA-3H-AB3X.D1001F1F-5707-4D67-B915-C8899511D3EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).